Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A24C, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A24C-01A (Primary Tumor).

OC#: TSS #:

Procurement Date: Laterality: NA

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 3.2 x 2.8 x 4.5 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

1CD-0-3

Melanoma, malignant 8720/3

Site: Skin, trunk C44.5 for 4/22/11

Source: NCI Genomic Data Commons file d47728f1-c8a9-449c-b28a-50b23611915d (TCGA-EB-A24C.C8324D05-F859-41E1-AF45-8211A305E3CF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).